Somatic mutation profile of tumor specimen TARGET-10-PARJXW-09A (aliquot TARGET-10-PARJXW-09A-01D) from TARGET case TARGET-10-PARJXW, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 14.8 years (5,413 days).
Specimen TARGET-10-PARJXW-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d7562d36-76f6-407a-9a62-b653a3f561a5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PARJXW-14A (Bone Marrow Normal), aliquot TARGET-10-PARJXW-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d1809ced-9751-420f-8677-d149d1d50d6d

The open-access MAF lists 18 somatic variants for this specimen: 15 protein-altering or splice-affecting, 1 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 11, In Frame Ins 2, 3'UTR 1, Silent 1, 5'UTR 1, Frame Shift Ins 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FBXW7 | c.2065C>T p.R689W (on ENST00000281708 / NM_001349798.2; = p.R609W on NM_018315.5) | Missense Mutation (SNP) | VAF 10/87 reads (11%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55895191, COSV55934968; called by muse, mutect2, varscan2
- FBXW7 | c.1393C>T p.R465C (on ENST00000281708 / NM_001349798.2; = p.R385C on NM_018315.5) | Missense Mutation (SNP) | VAF 39/99 reads (39%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs867384286, COSV55891008, COSV55897912, COSV99654845; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ADGRA1 | c.187G>A p.A63T | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT tolerated (0.83); PolyPhen benign (0.01); catalogued as rs777157501, COSV66927189; called by muse, mutect2, varscan2
- AGMO | c.1143T>A p.F381L | Missense Mutation (SNP) | VAF 55/137 reads (40%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as COSV61122954; called by muse, mutect2, varscan2
- IL7R | c.732_733insTGTCCGGATGGGCGT p.T244_I245insCPDGR | In Frame Ins (INS) | VAF 22/158 reads (14%) | catalogued as COSV57412961; called by mutect2, pindel*
- KCNQ3 | c.1697C>T p.T566M | Missense Mutation (SNP) | VAF 38/95 reads (40%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.727); catalogued as rs746403693, COSV66480722; called by muse, mutect2, varscan2
- LTBR | c.802G>A p.G268R | Missense Mutation (SNP) | VAF 25/57 reads (44%) | SIFT tolerated (0.23); PolyPhen benign (0.036); catalogued as COSV57439866; called by muse, mutect2, varscan2
- M1AP | c.752G>T p.R251I | Missense Mutation (SNP) | VAF 52/145 reads (36%) | SIFT tolerated (0.22); PolyPhen benign (0.281); catalogued as COSV51847880; called by muse, mutect2, varscan2
- MELK | c.976C>T p.R326W | Missense Mutation (SNP) | VAF 11/73 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); catalogued as rs148081976, COSV53202385; called by muse, mutect2, varscan2
- USP7 | c.277_278insTTACCCT p.R93Lfs*34 | Frame Shift Ins (INS) | VAF 19/61 reads (31%) | catalogued as COSV61217180; called by mutect2, pindel, varscan2
- WDR3 | c.2521G>A p.E841K | Missense Mutation (SNP) | VAF 16/150 reads (11%) | SIFT tolerated (0.75); PolyPhen benign (0.041); catalogued as rs751941966, COSV60452577; called by muse, mutect2
- FLNC | c.5639T>C p.F1880S | Missense Mutation (SNP) | VAF 9/92 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MKS1 | c.1667C>G p.T556S | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- SNED1 | c.840_841insAGCAGGGCCTCAAAC p.N280_G281insSRASN | In Frame Ins (INS) | VAF 10/42 reads (24%) | called by pindel, varscan2
- SYNRG | c.997G>T p.E333* | Nonsense Mutation (SNP) | VAF 66/180 reads (37%) | called by muse, mutect2, varscan2
- NPAS4 | c.1815G>T p.V605= | Silent (SNP) | VAF 10/132 reads (8%) | called by muse, mutect2
- CD8A | c.*101C>A | 3'UTR (SNP) | VAF 27/74 reads (36%) | called by muse, mutect2, varscan2
- TMEM116 | c.-71G>T | 5'UTR (SNP) | VAF 6/59 reads (10%) | called by muse, mutect2
